Somatic mutation profile of tumor specimen TCGA-EE-A3JB-06A (aliquot TCGA-EE-A3JB-06A-11D-A21A-08) from TCGA case TCGA-EE-A3JB, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 77.4 years (28,259 days).
Specimen TCGA-EE-A3JB-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c11d8331-6134-4e69-b07f-f7713838621d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A3JB-10A (Blood Derived Normal), aliquot TCGA-EE-A3JB-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e269fe2-61f3-41de-a662-10e21c2c7f40

The open-access MAF lists 761 somatic variants for this specimen: 497 protein-altering or splice-affecting, 244 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 444, Silent 244, Nonsense Mutation 30, Splice Site 11, RNA 8, Intron 8, Splice Region 5, Frame Shift Del 4, 5'Flank 2, Translation Start Site 1, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (750 of 761; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDKN2A | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 26/45 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.665); catalogued as CM034218, CM095540, COSV58683071, COSV58683670; called by muse, mutect2, varscan2
- MAP2K1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 34/91 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1057519732, COSV61068297; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RICTOR | c.3302C>T p.S1101L | Missense Mutation (SNP) | VAF 25/89 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs776074870, COSV57119127; called by muse, mutect2, varscan2
- AASDHPPT | c.31G>C p.V11L | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV53789417; called by muse, mutect2, varscan2
- ACACA | c.4779C>T p.I1593= | Splice Region (SNP) | VAF 21/98 reads (21%) | catalogued as rs763027565; called by muse, mutect2, varscan2
- ACTL6A | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.78); catalogued as COSV66999111; called by muse, mutect2, varscan2
- ADAM28 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56100183, COSV99738446; called by muse, mutect2, varscan2
- ADAM28 | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 110/299 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as COSV56101914; called by muse, mutect2, varscan2
- ADAM29 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.26); catalogued as rs1456628852, COSV63664876; called by muse, mutect2, varscan2
- ADAMTS9 | c.5639G>A p.G1880E | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55784107; called by muse, mutect2, varscan2
- ADCY5 | c.1618A>G p.M540V | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59199658; called by muse, mutect2, varscan2
- ADCY8 | c.1526G>A p.G509E | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53901399; called by muse, mutect2, varscan2
- ADGRB3 | c.3532C>T p.P1178S | Missense Mutation (SNP) | VAF 79/159 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV53238942, COSV53247980; called by muse, mutect2, varscan2
- ADGRL2 | c.3826A>G p.S1276G (on ENST00000370717 / NM_001366005.1; = p.S1220G on NM_012302.4) | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV54673938; called by muse, mutect2, varscan2
- ADGRV1 | c.1820G>A p.G607E | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV67988413; called by muse, mutect2, varscan2
- ADGRV1 | c.11098G>A p.D3700N | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV67988415; called by muse, mutect2, varscan2
- AFM | c.739T>A p.F247I | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56920740; called by muse, mutect2, varscan2
- AGL | c.2011G>A p.V671I | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1243258727, COSV54054286; called by muse, mutect2, varscan2
- ALG14 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs1415210510, COSV64635168; called by muse, mutect2, varscan2
- ALG8 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55200383; called by muse, mutect2, varscan2
- ALKBH4 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV52961290; called by muse, mutect2, varscan2
- AMIGO2 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 77/247 reads (31%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.739); catalogued as COSV56974663, COSV99873639; called by muse, mutect2, varscan2
- AMIGO2 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.478); catalogued as COSV56974676; called by muse, mutect2, varscan2
- ANGPTL5 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV57532936; called by muse, mutect2
- ANKRD53 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV55537143, COSV99721273; called by muse, mutect2, varscan2
- ANO5 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.18); catalogued as COSV61086839; called by muse, mutect2, varscan2
- AP3B2 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.025); catalogued as COSV55610905; called by muse, mutect2, varscan2
- APLP2 | c.2020C>T p.L674F | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.894); catalogued as COSV99600030; called by muse, mutect2, varscan2
- APOB | c.10375G>A p.E3459K | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.996); catalogued as COSV99267567; called by muse, mutect2, varscan2
- APOB | c.10374G>A p.M3458I | Missense Mutation (SNP) | VAF 65/237 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51955902; called by muse, mutect2, varscan2
- APOL4 | c.826A>G p.R276G (on ENST00000352371 / NM_145660.2; = p.R273G on NM_030643.4) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as COSV60654866; called by muse, mutect2
- AREG | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as rs1283640826; called by muse, mutect2, varscan2
- ARHGAP39 | c.3252G>T p.*1084Yext*168 (on ENST00000276826 / NM_001308208.2; = p.*1115Yext*168 on NM_025251.2) | Nonstop Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV52772139; called by muse, mutect2, varscan2
- ARID5A | c.202T>C p.F68L | Missense Mutation (SNP) | VAF 79/232 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62591339; called by muse, mutect2, varscan2
- ARMC3 | c.2505G>T p.K835N | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.415); catalogued as COSV99958762; called by muse, mutect2, varscan2
- ARMC3 | c.2506G>A p.G836R | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV53063550; called by muse, mutect2, varscan2
- ARPP21 | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51800228, COSV51800932; called by muse, mutect2, varscan2
- ASTN1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV56073683; called by muse, mutect2, varscan2
- ATF5 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.766); catalogued as COSV61312570; called by muse, mutect2, varscan2
- ATP13A2 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1443334892, COSV58701485; called by muse, mutect2, varscan2
- ATP1A2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 158/386 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.113); catalogued as COSV63404437; called by muse, varscan2
- AZGP1 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs948529445, COSV52797423; called by muse, varscan2
- BEX3 | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 67/376 reads (18%) | catalogued as COSV55420975; called by muse, mutect2, varscan2
- BMP3 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.176); catalogued as COSV51087379; called by muse, mutect2, varscan2
- BOC | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs374255523; called by muse, mutect2, varscan2
- BRINP1 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV56291351; called by muse, mutect2, varscan2
- BRINP2 | c.1061A>G p.N354S | Missense Mutation (SNP) | VAF 74/482 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as COSV64178335; called by muse, mutect2, varscan2
- BSN | c.5819C>T p.P1940L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV56519515; called by muse, mutect2, varscan2
- C11orf1 | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1432058988, COSV52789159; called by muse, mutect2, varscan2
- C12orf45 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs746380021, COSV55012856; called by muse, mutect2, varscan2
- C12orf54 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs868088728, COSV58359933; called by muse, mutect2, varscan2
- C16orf70 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 46/270 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54627841; called by muse, mutect2, varscan2
- C22orf42 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 81/313 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.503); catalogued as COSV66076220; called by muse, mutect2, varscan2
- C2CD3 | c.1229C>T p.S410F | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs764365001, COSV58094630; called by muse, mutect2, varscan2
- C4BPB | c.111G>T p.K37N | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV54691791; called by muse, mutect2, varscan2
- CACNA1C | c.1187T>C p.V396A | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59735770; called by muse, mutect2, varscan2
- CAMTA1 | c.265A>C p.K89Q | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57908626; called by muse, mutect2, varscan2
- CAPN9 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751244678, COSV55235540; called by muse, mutect2, varscan2
- CARMIL2 | c.1176G>A p.W392* | Nonsense Mutation (SNP) | VAF 27/120 reads (23%) | catalogued as COSV58028211; called by muse, mutect2, varscan2
- CASR | c.2923C>T p.P975S (on ENST00000490131; = p.P1052S on NM_000388.4) | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.528); catalogued as COSV56138721; called by muse, mutect2, varscan2
- CATSPERD | c.1916G>C p.G639A | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.061); catalogued as COSV58465962; called by muse, mutect2, varscan2
- CBX7 | c.605C>A p.A202D | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV53359361; called by muse, mutect2, varscan2
- CBX7 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV53359371; called by muse, mutect2, varscan2
- CCDC141 | c.4016A>C p.Q1339P | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV55376230; called by muse, mutect2, varscan2
- CCK | c.229A>T p.M77L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV58184077; called by muse, mutect2, varscan2
- CCNB3 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV52075352; called by muse, mutect2, varscan2
- CD300E | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | catalogued as COSV60790899; called by muse, mutect2, varscan2
- CD37 | c.584A>G p.K195R | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.453); catalogued as rs746341276, COSV60544703; called by muse, mutect2, varscan2
- CD96 | c.612A>C p.E204D (on ENST00000283285 / NM_198196.3; = p.E188D on NM_005816.5) | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV51918279; called by muse, mutect2, varscan2
- CDH10 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as rs1402706331, COSV52570966, COSV52580434; called by muse, mutect2, varscan2
- CDH4 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs375893301; called by muse, mutect2, varscan2
- CENPF | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as COSV65276077; called by muse, mutect2, varscan2
- CFAP221 | c.1453C>T p.R485C | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs765273288, COSV54653795; called by muse, mutect2, varscan2
- CHD9 | c.853A>C p.S285R | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as COSV68298701; called by muse, mutect2, varscan2
- CHGB | c.772C>T p.R258* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as rs779546426, COSV66760871, COSV66761387; called by muse, mutect2, varscan2
- CHRM3 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487020414, COSV55093240, COSV55095451; called by muse, mutect2, varscan2
- CHRNB3 | c.1073C>T p.S358F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV51495794; called by muse, mutect2
- CHST5 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs769120794, COSV60340043; called by muse, mutect2, varscan2
- CLASP1 | c.3112G>A p.D1038N | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV55328325; called by muse, mutect2, varscan2
- CLCN1 | c.1225G>A p.G409R | Missense Mutation (SNP) | VAF 62/250 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58371138, COSV58371144; called by muse, mutect2, varscan2
- CLEC4G | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV61003570; called by muse, mutect2, varscan2
- CLNS1A | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54440149; called by muse, mutect2, varscan2
- CNTN1 | c.1973T>A p.I658N | Missense Mutation (SNP) | VAF 89/223 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV61641529; called by muse, mutect2, varscan2
- CNTN4 | c.3014C>T p.S1005L | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs753714750, COSV61867614; called by muse, mutect2, varscan2
- CNTN5 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.702); catalogued as rs866845091, COSV54279011; called by muse, mutect2, varscan2
- CNTNAP4 | c.2182G>A p.G728R | Missense Mutation (SNP) | VAF 82/246 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.223); catalogued as COSV56663657; called by muse, mutect2, varscan2
- COL22A1 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.321); catalogued as COSV57343726; called by muse, mutect2, varscan2
- COL26A1 | c.646C>T p.P216S (on ENST00000313669 / NM_001278563.3; = p.P214S on NM_133457.4) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV58126814; called by muse, mutect2, varscan2
- COL3A1 | c.1762-1G>A p.X588_splice | Splice Site (SNP) | VAF 25/134 reads (19%) | catalogued as COSV58591126, COSV58594445; called by muse, varscan2
- COL4A5 | c.4045G>A p.E1349K | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as CD115550, COSV60364536; called by muse, mutect2, varscan2
- COL6A2 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV56008531; called by muse, mutect2, varscan2
- CPZ | c.1585C>T p.R529C (on ENST00000360986 / NM_001014447.3; = p.R518C on NM_003652.3) | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs200918270, COSV59923838; called by muse, mutect2, varscan2
- CRYBB1 | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.483); catalogued as COSV53233756; called by muse, mutect2, varscan2
- CSMD2 | c.8522C>A p.P2841Q | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as rs878885361, COSV53925761; called by muse, mutect2, varscan2
- CSMD2 | c.2528C>G p.S843C | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV53910497, COSV53925780; called by muse, mutect2, varscan2
- CXorf21 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV66762826; called by muse, mutect2, varscan2
- CYP11A1 | c.1163A>C p.H388P | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV51432815; called by muse, mutect2, varscan2
- CYP2A7 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52502356; called by muse, mutect2, varscan2
- CYTH1 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63121540; called by muse, mutect2, varscan2
- DAO | c.707T>C p.V236A | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV57323119; called by muse, mutect2, varscan2
- DBN1 | c.1024A>G p.S342G | Missense Mutation (SNP) | VAF 106/200 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV52790465; called by muse, mutect2, varscan2
- DCP2 | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.71); catalogued as rs781502312, COSV66617405; called by muse, mutect2, varscan2
- DDC | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63565895; called by muse, mutect2, varscan2
- DDX10 | c.2085+1G>A p.X695_splice | Splice Site (SNP) | VAF 39/298 reads (13%) | catalogued as COSV59436535; called by muse, varscan2
- DDX46 | c.2920C>T p.P974S | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV100844908, COSV62799795; called by muse, mutect2, varscan2
- DDX60L | c.5110C>T p.H1704Y | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV52716016; called by muse, mutect2, varscan2
- DEF8 | c.214C>T p.R72W (on ENST00000268676 / NM_207514.3; = p.R11W on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs776085470, COSV51919754, COSV99240677; called by muse, mutect2, varscan2
- DENND5A | c.2588C>T p.S863F | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100065151; called by muse, mutect2, varscan2
- DEUP1 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.669); catalogued as COSV53213436; called by muse, mutect2
- DGKI | c.1675C>T p.R559* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as rs1259961080, COSV55934682; called by muse, mutect2, varscan2
- DIDO1 | c.6338G>A p.R2113K | Missense Mutation (SNP) | VAF 101/217 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV56626321; called by muse, mutect2, varscan2
- DIRAS3 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.811); catalogued as rs866270680, COSV63970879; called by muse, mutect2, varscan2
- DLG1 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 81/211 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58385559, COSV58388614; called by muse, mutect2, varscan2
- DNAAF1 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs781004949, COSV57577788; called by muse, mutect2, varscan2
- DNAH1 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as COSV101326911; called by muse, mutect2, varscan2
- DNAH1 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV70235031; called by muse, mutect2, varscan2
- DNAH11 | c.8723C>T p.T2908I | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.543); catalogued as COSV60962970, COSV60980471; called by muse, mutect2, varscan2
- DNAH11 | c.11888C>T p.S3963F | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771506355, COSV60962985; called by muse, mutect2, varscan2
- DNAH3 | c.10234C>T p.P3412S | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.209); catalogued as COSV54530502; called by muse, mutect2, varscan2
- DNAH3 | c.9067C>T p.Q3023* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV54530523; called by muse, mutect2, varscan2
- DNAH3 | c.5809G>A p.E1937K | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0.202); catalogued as COSV54530540; called by muse, mutect2, varscan2
- DNAH5 | c.6842-2A>C p.X2281_splice | Splice Site (SNP) | VAF 40/85 reads (47%) | catalogued as COSV54234516; called by muse, mutect2, varscan2
- DNAH5 | c.5866A>C p.T1956P | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54234529; called by muse, mutect2, varscan2
- DNM2 | c.2516C>T p.P839L (on ENST00000355667 / NM_001005360.3; = p.P835L on NM_004945.3) | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.981); catalogued as COSV53034381; called by muse, mutect2, varscan2
- DPRX | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV64949701; called by muse, mutect2, varscan2
- DSEL | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV100025821, COSV59492578; called by muse, mutect2, varscan2
- DYSF | c.3304G>A p.E1102K | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV50456295; called by muse, mutect2, varscan2
- EDRF1 | c.1370C>T p.A457V (on ENST00000356792 / NM_001202438.2; = p.A423V on NM_015608.2) | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61764760; called by muse, mutect2, varscan2
- EFHC1 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 93/162 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as COSV64136477; called by muse, mutect2, varscan2
- ELAVL1 | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60967236; called by muse, mutect2, varscan2
- ELF4 | c.1909C>T p.L637F | Missense Mutation (SNP) | VAF 52/312 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs772417954, COSV100257566; called by muse, varscan2
- ENPEP | c.2864A>G p.E955G | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV54452991; called by muse, mutect2, varscan2
- ENPP1 | c.1888C>T p.P630S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV62933527; called by muse, mutect2, varscan2
- ENPP2 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.174); catalogued as COSV50019890; called by muse, mutect2, varscan2
- EP300 | c.4918G>T p.E1640* | Nonsense Mutation (SNP) | VAF 22/139 reads (16%) | catalogued as COSV54336147; called by muse, mutect2, varscan2
- EPHA1 | c.1974A>C p.L658F | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51972533; called by muse, mutect2, varscan2
- EPHB2 | c.2106G>A p.M702I (on ENST00000400191 / NM_001309193.2; = p.M703I on NM_004442.7) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65863525; called by muse, varscan2
- EPHX3 | c.858G>A p.R286= | Splice Region (SNP) | VAF 20/61 reads (33%) | catalogued as COSV55655914; called by muse, mutect2, varscan2
- ERICH3 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs769315284, COSV58600498; called by muse, mutect2, varscan2
- ESS2 | c.1250G>A p.S417N | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52817369; called by muse, mutect2
- EXOC1 | c.2264C>T p.A755V | Missense Mutation (SNP) | VAF 62/114 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV62120809; called by muse, mutect2, varscan2
- FAM47A | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867182777, COSV60497794; called by muse, mutect2, varscan2
- FARP1 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 95/159 reads (60%) | SIFT tolerated (0.24); PolyPhen benign (0.172); catalogued as COSV60340666; called by muse, mutect2, varscan2
- FAS | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58239224; called by muse, mutect2, varscan2
- FAT3 | c.9701C>T p.P3234L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1354781247, COSV53131021, COSV53143812; called by muse, mutect2, varscan2
- FBXO40 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753051384, COSV57524628; called by muse, mutect2, varscan2
- FCGBP | c.10810G>A p.E3604K | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs759388502; called by muse, mutect2, varscan2
- FCGBP | c.8047G>A p.G2683S | Missense Mutation (SNP) | VAF 23/263 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.186); catalogued as rs1325720220; called by muse, mutect2, varscan2
- FER1L6 | c.4727C>T p.P1576L | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67550897; called by muse, mutect2, varscan2
- FIBCD1 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV53394133; called by muse, mutect2, varscan2
- FLT1 | c.2660A>T p.H887L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV56731932; called by muse, mutect2, varscan2
- FN1 | c.4202C>T p.P1401L | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.996); catalogued as COSV100118087; called by muse, mutect2, varscan2
- FN1 | c.4201C>T p.P1401S | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.978); catalogued as COSV100118090; called by muse, mutect2, varscan2
- FNDC8 | c.593G>A p.W198* | Nonsense Mutation (SNP) | VAF 29/123 reads (24%) | catalogued as rs746857060, COSV50101991; called by muse, mutect2, varscan2
- FOXRED2 | c.791A>T p.N264I | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV53400525; called by muse, mutect2, varscan2
- FRAS1 | c.4969G>A p.G1657S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV53590411, COSV53621954; called by muse, mutect2, varscan2
- FRAS1 | c.8569C>T p.R2857W | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs552527828, COSV53598349; called by muse, mutect2, varscan2
- FSHR | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58617717; called by muse, mutect2, varscan2
- FTSJ1 | c.572-1G>A p.X191_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | catalogued as COSV50026012; called by muse, mutect2, varscan2
- GAB3 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.691); catalogued as COSV65819973; called by muse, mutect2, varscan2
- GABRB2 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV50920532; called by muse, mutect2, varscan2
- GALNT18 | c.1679G>A p.G560E | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1035041054, COSV57151646; called by muse, mutect2, varscan2
- GCNA | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 110/608 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV101032425, COSV65466748; called by muse, varscan2
- GIGYF2 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1228793071, COSV65250825; called by muse, mutect2, varscan2
- GINS3 | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58920006; called by muse, varscan2
- GIPC2 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs138753471, COSV63379834; called by muse, mutect2, varscan2
- GIT2 | c.700C>A p.L234I | Missense Mutation (SNP) | VAF 184/514 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.742); catalogued as COSV58082273; called by muse, mutect2, varscan2
- GK2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV62627432; called by muse, mutect2, varscan2
- GK2 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); catalogued as COSV62627436; called by muse, mutect2, varscan2
- GLRA2 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54342836; called by muse, mutect2, varscan2
- GMEB1 | c.1713A>T p.L571F | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV53795106; called by muse, mutect2, varscan2
- GOLGB1 | c.4175C>T p.P1392L | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as COSV61467290, COSV61469494; called by muse, mutect2, varscan2
- GPD1 | c.42G>A p.W14* | Nonsense Mutation (SNP) | VAF 65/143 reads (45%) | catalogued as COSV56548435; called by muse, mutect2, varscan2
- GPR137 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 66/218 reads (30%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV57403471; called by mutect2, varscan2
- GPR137 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV100464463; called by muse, mutect2, varscan2
- GPX1 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV69042898; called by muse, mutect2, varscan2
- GRIA4 | c.519A>C p.K173N | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV56904150; called by muse, mutect2, varscan2
- GRID2 | c.603A>T p.E201D | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as COSV56222935; called by muse, mutect2, varscan2
- GRIN2A | c.3863G>A p.R1288H | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778951185, COSV58035660; called by muse, mutect2, varscan2
- GRM3 | c.2489C>T p.P830L | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64474244; called by muse, mutect2, varscan2
- GUCY2C | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.85); PolyPhen benign (0.048); catalogued as rs867791055, COSV53788451; called by muse, mutect2, varscan2
- HCFC2 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1343070546, COSV57558996; called by muse, mutect2, varscan2
- HCN4 | c.3533C>T p.P1178L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV56083943; called by muse, mutect2, varscan2
- HCRTR1 | c.1090A>G p.K364E | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); catalogued as COSV65483881; called by muse, mutect2, varscan2
- HEPHL1 | c.947G>A p.R316K | Missense Mutation (SNP) | VAF 49/362 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.401); catalogued as COSV59893186; called by muse, mutect2, varscan2
- HERC5 | c.419T>A p.I140K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1322520060, COSV52037998; called by muse, varscan2
- HJV | c.937G>A p.D313N (on ENST00000336751 / NM_213653.4; = p.D200N on NM_145277.5) | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs781952904, COSV60952395; called by muse, mutect2, varscan2
- HRNR | c.6038C>T p.S2013F | Missense Mutation (SNP) | VAF 99/2518 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.258); catalogued as COSV64259562; called by muse, mutect2
- HSD3B1 | c.835C>G p.R279G | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.134); catalogued as COSV52489793, COSV52491178; called by muse, mutect2, varscan2
- HVCN1 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54373007; called by muse, mutect2, varscan2
- HYDIN | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV55489146; called by muse, mutect2, varscan2
- ICAM5 | c.1876G>A p.D626N | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs373911810, COSV99703509; called by muse, mutect2, varscan2
- ICE1 | c.3911C>T p.P1304L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV56827723; called by muse, mutect2, varscan2
- IDS | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557339910, COSV61712862; called by muse, mutect2, varscan2
- IFI44 | c.181A>G p.I61V | Missense Mutation (SNP) | VAF 58/256 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV66075055; called by muse, mutect2, varscan2
- IFRD1 | c.917dup p.Y306* | Nonsense Mutation (INS) | VAF 23/84 reads (27%) | catalogued as COSV50046121; called by mutect2, pindel, varscan2
- IFT122 | c.1853C>T p.S618F (on ENST00000348417 / NM_052989.3; = p.S559F on NM_018262.4) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1371012508, COSV56204581; called by muse, mutect2, varscan2
- IGSF1 | c.2930C>T p.P977L | Missense Mutation (SNP) | VAF 154/368 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764960641, COSV63838302; called by muse, mutect2, varscan2
- IGSF5 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); catalogued as COSV66029297, COSV66030688; called by muse, mutect2, varscan2
- IL1R2 | c.511A>T p.K171* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | catalogued as COSV60208042; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1043A>G p.K348R | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.985); catalogued as COSV61164065; called by muse, mutect2
- IL23R | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 32/252 reads (13%) | catalogued as COSV61374905; called by muse, mutect2
- IL4R | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 75/178 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.741); catalogued as rs753586692, COSV50149735; called by muse, mutect2, varscan2
- INTS4 | c.2657G>A p.G886D | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.505); catalogued as rs978325311, COSV59019437; called by muse, mutect2, varscan2
- IRF2BP1 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56194015; called by muse, mutect2, varscan2
- IRF7 | c.223G>A p.A75T (on ENST00000397566; = p.A62T on NM_001572.5) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52757672; called by muse, mutect2, varscan2
- ITGA3 | c.2608C>T p.P870S | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.076); catalogued as COSV50318216; called by muse, mutect2, varscan2
- ITGAD | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 79/196 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.07); catalogued as COSV66758534; called by muse, mutect2, varscan2
- ITPR2 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67269696; called by muse, mutect2, varscan2
- KBTBD8 | c.1093C>T p.H365Y | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV55129689; called by muse, mutect2, varscan2
- KCNB1 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); catalogued as rs976018808, COSV100870354, COSV65569070; called by muse, mutect2, varscan2
- KCNG4 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs1433852981, COSV57583799; called by muse, mutect2, varscan2
- KCNJ12 | c.283T>C p.W95R | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100055994; called by muse, mutect2, varscan2
- KCNK1 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64035473; called by muse, mutect2, varscan2
- KDM5B | c.3947C>T p.P1316L | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.231); catalogued as COSV52509266; called by muse, mutect2, varscan2
- KIAA1958 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.462); catalogued as rs762891804, COSV61725006; called by muse, mutect2, varscan2
- KIF20B | c.5026C>T p.P1676S (on ENST00000371728 / NM_001284259.2; = p.P1636S on NM_016195.4) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV53309730; called by muse, mutect2, varscan2
- KIF4B | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV70530096; called by muse, mutect2, varscan2
- KIR3DL3 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.646); catalogued as COSV52549064; called by muse, mutect2, varscan2
- KLHL21 | c.1528C>T p.L510F | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV66553713; called by muse, mutect2, varscan2
- KLHL4 | c.1375A>C p.I459L | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV64143996; called by muse, mutect2
- KLHL8 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as COSV56748355; called by muse, mutect2, varscan2
- KNTC1 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.075); catalogued as COSV61081299; called by muse, mutect2
- KRTAP19-6 | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 109/298 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV61844125; called by muse, mutect2, varscan2
- KYNU | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51586034; called by muse, mutect2, varscan2
- LIMA1 | c.395C>G p.S132* | Nonsense Mutation (SNP) | VAF 54/113 reads (48%) | catalogued as rs768965142, COSV57966408; called by muse, mutect2, varscan2
- LIPH | c.1121A>C p.H374P | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as COSV56184630; called by muse, mutect2, varscan2
- LMLN | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as rs1250893823, COSV54563254, COSV99502096; called by muse, mutect2, varscan2
- LMO7 | c.4517C>T p.S1506F (on ENST00000357063; = p.S1187F on NM_005358.5) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58540482; called by muse, mutect2, varscan2
- LOXL2 | c.1489G>A p.G497R | Missense Mutation (SNP) | VAF 77/234 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs370872248; called by muse, mutect2, varscan2
- LRP1B | c.7094C>A p.P2365Q | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67238817, COSV67251298; called by muse, mutect2
- LRRC7 | c.4452G>A p.Q1484= (on ENST00000651989 / NM_001370785.2; = p.Q1404= on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 9/60 reads (15%) | catalogued as COSV99229376; called by muse, mutect2, varscan2
- LRRC7 | c.4452+1G>A p.X1484_splice (on ENST00000651989 / NM_001370785.2; = p.X1404_splice on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 9/60 reads (15%) | catalogued as COSV99229377; called by muse, mutect2, varscan2
- LYN | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs1210415750, COSV70205934; called by muse, mutect2, varscan2
- LYST | c.4069G>A p.E1357K | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV67708765; called by muse, mutect2, varscan2
- MAGEA6 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.463); catalogued as COSV61449131; called by muse, mutect2, varscan2
- MAGEB6 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.79); catalogued as COSV66872510; called by muse, mutect2, varscan2
- MAGEC3 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.117); catalogued as rs751667407, COSV71610043; called by muse, mutect2, varscan2
- MAPKAPK5 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 68/365 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV73411102; called by muse, mutect2, varscan2
- ME1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63840303; called by muse, mutect2, varscan2
- MED1 | c.3272C>T p.S1091F | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV56126094; called by muse, mutect2, varscan2
- MERTK | c.2510G>C p.W837S | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99775202; called by muse, mutect2, varscan2
- MERTK | c.2511G>A p.W837* | Nonsense Mutation (SNP) | VAF 32/83 reads (39%) | catalogued as COSV99775204; called by muse, mutect2, varscan2
- MET | c.3836G>A p.R1279K | Missense Mutation (SNP) | VAF 117/400 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59263314, COSV59268041; called by muse, mutect2, varscan2
- METRNL | c.581C>T p.T194I | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as rs996302202, COSV60760963; called by muse, mutect2, varscan2
- MGA | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV54956811; called by muse, mutect2, varscan2
- MICALL2 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs549018950, COSV52516567; called by muse, mutect2
- MIER3 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV61229727; called by muse, mutect2, varscan2
- MLIP | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 99/149 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1178590734, COSV51430243; called by muse, mutect2, varscan2
- MMP26 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs371733570; called by muse, mutect2, varscan2
- MNDA | c.236T>C p.V79A | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT tolerated (0.89); PolyPhen benign (0.03); catalogued as rs775626811, COSV63741230; called by muse, mutect2, varscan2
- MORC1 | c.2103G>A p.M701I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV51723260; called by muse, mutect2, varscan2
- MRC2 | c.2458G>A p.D820N | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs1424812493, COSV57641221; called by muse, mutect2, varscan2
- MRGPRX3 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV66934191; called by muse, mutect2, varscan2
- MRPL50 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV66406211; called by mutect2, varscan2
- MUC17 | c.8714A>C p.E2905A | Missense Mutation (SNP) | VAF 182/622 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.636); catalogued as COSV60292959; called by muse, mutect2, varscan2
- MXRA8 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV58510966, COSV58511048; called by muse, mutect2, varscan2
- MYH1 | c.5398C>T p.R1800C | Missense Mutation (SNP) | VAF 85/162 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs377494042; called by muse, mutect2, varscan2
- MYO1H | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV60447333; called by muse, mutect2, varscan2
- MYO5A | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV62561694; called by muse, mutect2, varscan2
- NASP | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV63113618; called by muse, mutect2, varscan2
- NAT1 | c.740A>G p.K247R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.216); catalogued as COSV56985713; called by muse, mutect2, varscan2
- NCOA6 | c.5939T>C p.L1980P | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs371027349; called by muse, mutect2
- NDNF | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as COSV65633943; called by muse, mutect2, varscan2
- NDST4 | c.2238G>A p.W746* | Nonsense Mutation (SNP) | VAF 39/170 reads (23%) | catalogued as COSV52124914; called by muse, mutect2, varscan2
- NDUFAF5 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs894455128, COSV65247133; called by muse, mutect2, varscan2
- NEXMIF | c.3950C>T p.S1317F | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs865876656, COSV50043567; called by muse, mutect2, varscan2
- NIBAN1 | c.1804T>G p.S602A | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV62285777; called by muse, mutect2
- NINL | c.2111C>T p.P704L | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV99626165; called by muse, mutect2, varscan2
- NLRP13 | c.2095G>A p.D699N | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.113); catalogued as COSV61621983; called by muse, mutect2, varscan2
- NLRP13 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs748234269, COSV61621131; called by muse, mutect2, varscan2
- NLRP8 | c.2687G>T p.C896F | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV52589548; called by muse, mutect2, varscan2
- NOL6 | c.3211C>T p.L1071F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53043023; called by muse, mutect2, varscan2
- NOTCH3 | c.805C>A p.Q269K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54638530; called by muse, mutect2, varscan2
- NOTCH4 | c.2873C>T p.P958L | Missense Mutation (SNP) | VAF 65/110 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV100900960; called by muse, mutect2, varscan2
- NOTCH4 | c.2872C>T p.P958S | Missense Mutation (SNP) | VAF 65/110 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV100900961; called by muse, mutect2, varscan2
- NPAS3 | c.1369G>A p.E457K (on ENST00000356141 / NM_001164749.2; = p.E425K on NM_022123.3) | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs773753615, COSV60852060; called by mutect2, varscan2
- NPBWR1 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV58696681; called by mutect2, varscan2
- NPHP4 | c.3164C>T p.P1055L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1398568182, COSV65395762; called by muse, mutect2
- NPR2 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.034); catalogued as COSV61312091; called by muse, mutect2, varscan2
- NPY1R | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs867872539, COSV56715091; called by muse, mutect2, varscan2
- NRXN1 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.137); catalogued as rs780954241, COSV68022190; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSFL1C | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV99401587; called by muse, mutect2, varscan2
- NT5C1B | c.707C>T p.S236L (on ENST00000359846 / NM_001199086.2; = p.S176L on NM_033253.4) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); catalogued as COSV58394635, COSV58397929; called by muse, varscan2
- NUP214 | c.5231C>T p.S1744F | Missense Mutation (SNP) | VAF 65/121 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV63910614; called by muse, mutect2, varscan2
- NYNRIN | c.5068C>T p.L1690F | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.438); catalogued as COSV101230683; called by muse, mutect2, varscan2
- OLFML2B | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1286835583, COSV54195040; called by muse, mutect2, varscan2
- OR11G2 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 94/180 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.208); catalogued as rs748078692, COSV62132633; called by muse, mutect2, varscan2
- OR14I1 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.158); catalogued as rs1283196559, COSV61200136; called by muse, mutect2, varscan2
- OR1F1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as COSV100484347, COSV58961387; called by muse, mutect2, varscan2
- OR2AT4 | c.604C>T p.L202F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0.023); catalogued as rs756247228, COSV59408046; called by muse, varscan2
- OR2C3 | c.587A>T p.N196I | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.855); catalogued as rs779833070, COSV63575360; called by muse, mutect2, varscan2
- OR2T2 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 86/419 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV61618380; called by muse, mutect2, varscan2
- OR4A15 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as COSV59033505; called by muse, mutect2, varscan2
- OR4D5 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV58307045; called by muse, mutect2, varscan2
- OR5D16 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 131/428 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as rs267602982, COSV65721414; called by muse, mutect2, varscan2
- OR6F1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100129410; called by muse, mutect2, varscan2
- OR8A1 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV52509045, COSV52509116; called by muse, mutect2, varscan2
- OR8D1 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.185); catalogued as COSV63441945; called by muse, mutect2, varscan2
- PCDH17 | c.2390A>T p.Y797F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as COSV64975608; called by muse, mutect2, varscan2
- PCDH18 | c.2656G>A p.D886N | Missense Mutation (SNP) | VAF 81/401 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs1040505669, COSV61267860; called by muse, mutect2, varscan2
- PCDHA5 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV65353678; called by muse, mutect2, varscan2
- PCDHB1 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782127622, COSV60631692; called by muse, mutect2, varscan2
- PCYT1B | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV63265450; called by muse, mutect2, varscan2
- PDE3B | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs765870867, COSV56385936; called by muse, mutect2, varscan2
- PDHA2 | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV54778748; called by muse, mutect2, varscan2
- PDPN | c.461G>A p.R154Q (on ENST00000621990; = p.R230Q on NM_006474.4) | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs147446446; called by muse, mutect2, varscan2
- PDSS2 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.09); catalogued as COSV64655715; called by muse, mutect2, varscan2
- PDZD2 | c.2914G>A p.D972N | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56862329; called by muse, mutect2, varscan2
- PDZD2 | c.8300G>A p.G2767E | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56862340; called by muse, mutect2, varscan2
- PGLYRP4 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV62835580; called by muse, mutect2, varscan2
- PIAS1 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV99987076; called by muse, mutect2, varscan2
- PIAS1 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV99987078; called by muse, mutect2, varscan2
- PIEZO2 | c.7763C>T p.P2588L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53291026; called by muse, mutect2, varscan2
- PIP4P2 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1378975239, COSV53440560; called by muse, mutect2, varscan2
- PITPNM3 | c.1847C>T p.P616L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV99338490, COSV99338974; called by muse, mutect2, varscan2
- PIWIL4 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.342); catalogued as rs758783384, COSV54410160; called by muse, mutect2, varscan2
- PKD1L1 | c.7250C>G p.P2417R | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.226); catalogued as COSV51843240, COSV51844813; called by muse, mutect2, varscan2
- PKHD1L1 | c.3095T>A p.L1032Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV65746036; called by muse, mutect2, varscan2
- PKHD1L1 | c.4204G>A p.V1402I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.077); catalogued as COSV65746040; called by muse, mutect2
- PKHD1L1 | c.9937G>A p.D3313N | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV65746044; called by muse, mutect2
- PKN2 | c.48G>A p.Q16= | Splice Region (SNP) | VAF 5/11 reads (45%) | catalogued as COSV60132553; called by muse, mutect2, varscan2
- PLB1 | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.046); catalogued as COSV59828779; called by muse, mutect2, varscan2
- PLEK | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52252506, COSV99311199; called by muse, mutect2, varscan2
- PLK1 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as rs749527952, COSV55620232; called by muse, mutect2, varscan2
- PLPP4 | c.556T>A p.L186M | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV64828394; called by muse, mutect2, varscan2
- PLPPR5 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54171364, COSV99586843; called by muse, mutect2, varscan2
- POLN | c.2515C>T p.Q839* | Nonsense Mutation (SNP) | VAF 98/185 reads (53%) | catalogued as COSV59051617; called by muse, mutect2, varscan2
- POLR2D | c.73+2T>C p.X25_splice | Splice Site (SNP) | VAF 4/34 reads (12%) | catalogued as rs949621579, COSV55758352, COSV99761098; called by muse, mutect2
- POM121 | c.1262G>A p.R421Q (on ENST00000434423; = p.R156Q on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 143/445 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.674); catalogued as rs1339766034, COSV57518250; called by muse, mutect2, varscan2
- PRAG1 | c.1018G>A p.G340S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.79); catalogued as rs1266404441, COSV58162978; called by muse, mutect2, varscan2
- PRAMEF1 | c.123G>A p.M41I | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV60011217; called by muse, mutect2, varscan2
- PRKCI | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV55520102; called by muse, mutect2, varscan2
- PRMT9 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.072); catalogued as COSV59360196; called by muse, mutect2, varscan2
- PRRT3 | c.1188G>A p.W396* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV55977666; called by muse, mutect2, varscan2
- PRUNE2 | c.5866C>A p.Q1956K | Missense Mutation (SNP) | VAF 74/151 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.122); catalogued as COSV65043186; called by muse, mutect2, varscan2
- PSD4 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV99831427; called by muse, mutect2, varscan2
- PSD4 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.018); catalogued as COSV99831429; called by muse, mutect2, varscan2
- PTPN22 | c.2111C>T p.S704F (on ENST00000359785 / NM_001193431.2; = p.S649F on NM_012411.5) | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63085586; called by muse, mutect2, varscan2
- PTPRR | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1174021927, COSV51726925; called by muse, mutect2, varscan2
- PUM2 | c.2813A>C p.K938T | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as COSV57582628; called by muse, mutect2, varscan2
- PWWP3B | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as COSV61800275; called by muse, mutect2, varscan2
- PWWP3B | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV61800287; called by muse, mutect2, varscan2
- PYGL | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53586732; called by muse, mutect2, varscan2
- RALA | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as COSV50049531; called by muse, mutect2
- RAMP2 | c.173T>A p.V58E | Missense Mutation (SNP) | VAF 84/296 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV53823177; called by muse, mutect2, varscan2
- RGR | c.680G>A p.G227D | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as rs1296499632, COSV63894326; called by muse, mutect2, varscan2
- RHBDD2 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 134/414 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV50087437; called by muse, mutect2, varscan2
- ROR2 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.824); catalogued as COSV65220622; called by muse, mutect2, varscan2
- RP1 | c.3013C>T p.H1005Y | Missense Mutation (SNP) | VAF 115/350 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55119747; called by muse, mutect2, varscan2
- RPAP1 | c.2116C>T p.P706S | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.172); catalogued as rs868340529, COSV58540386; called by muse, mutect2, varscan2
- RPS7 | c.278T>C p.V93A | Missense Mutation (SNP) | VAF 55/606 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV59233075; called by muse, mutect2
- RPTN | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 220/1180 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); catalogued as COSV60167761; called by muse, mutect2, varscan2
- RPTN | c.1043G>A p.R348K | Missense Mutation (SNP) | VAF 181/930 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.218); catalogued as COSV60167768; called by muse, mutect2, varscan2
- RTN2 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55594069; called by muse, mutect2, varscan2
- RUBCN | c.2480G>A p.R827Q | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1331389103, COSV56368306; called by muse, mutect2, varscan2
- RUBCN | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56368334; called by muse, mutect2, varscan2
- RYR2 | c.5160G>A p.M1720I | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.259); catalogued as COSV63693244; called by muse, mutect2, varscan2
- RYR2 | c.10201G>T p.E3401* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as COSV63693253; called by muse, mutect2
- S1PR1 | c.709T>C p.F237L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.147); catalogued as COSV59513570; called by muse, mutect2, varscan2
- SACS | c.6682G>T p.D2228Y | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs760182061, COSV66542392; called by muse, mutect2, varscan2
- SCAP | c.3088G>A p.D1030N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV55545671, COSV99650696; called by muse, mutect2, varscan2
- SCN10A | c.691+2T>A p.X231_splice | Splice Site (SNP) | VAF 18/115 reads (16%) | catalogued as COSV71861894; called by muse, mutect2, varscan2
- SCN1A | c.2657C>T p.S886F (on ENST00000303395 / NM_001202435.3; = p.S875F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57664511; called by muse, mutect2, varscan2
- SCN5A | c.3893C>A p.P1298H (on ENST00000333535 / NM_198056.3; = p.P1297H on NM_000335.5) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM033021, COSV61129071; called by muse, mutect2, varscan2
- SCN5A | c.2504C>T p.S835L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs199473163, CM045550, COSV100348736, COSV61122332; ClinVar: not provided; called by muse, mutect2, varscan2
- SCTR | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50029095; called by muse, mutect2, varscan2
- SEMG2 | c.991A>G p.T331A | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.492); catalogued as COSV65647608; called by muse, mutect2, varscan2
- SEPTIN14 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.4); catalogued as COSV66428537; called by muse, mutect2
- SERPINB4 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.898); catalogued as rs1568164065, COSV100345377, COSV61984331; called by muse, mutect2, varscan2
- SF3B2 | c.1885C>T p.P629S | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59428812; called by muse, mutect2, varscan2
- SGO2 | c.3160A>G p.K1054E | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as COSV63415880; called by muse, mutect2, varscan2
- SIRPD | c.481C>G p.H161D | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV67546831; called by muse, mutect2, varscan2
- SLC10A2 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55360009; called by muse, mutect2, varscan2
- SLC12A5 | c.1559G>A p.G520E (on ENST00000454036 / NM_001134771.2; = p.G497E on NM_020708.5) | Missense Mutation (SNP) | VAF 99/300 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54796023, COSV99715680; called by muse, mutect2, varscan2
- SLC17A4 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 309/425 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV64956537; called by muse, mutect2, varscan2
- SLC25A13 | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.062); catalogued as COSV55709300; called by muse, mutect2, varscan2
- SLC25A46 | c.925A>G p.M309V | Missense Mutation (SNP) | VAF 162/303 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs779270642, COSV63506833; called by muse, mutect2, varscan2
- SLC2A10 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 64/218 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63715122; called by muse, mutect2, varscan2
- SLC4A3 | c.3521C>T p.S1174F | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.274); catalogued as COSV56095091; called by muse, mutect2, varscan2
- SLC9A7 | c.1675G>A p.V559I | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as COSV100092691; called by muse, mutect2, varscan2
- SLC9C2 | c.2968G>A p.E990K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62946639; called by muse, mutect2, varscan2
- SLFN13 | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53192773; called by muse, mutect2, varscan2
- SMPX | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV65277763; called by muse, mutect2, varscan2
- SMS | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 30/246 reads (12%) | catalogued as COSV65114602; called by muse, mutect2, varscan2
- SOGA3 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64107184; called by muse, mutect2, varscan2
- SORBS1 | c.3650C>T p.A1217V (on ENST00000361941 / NM_001034954.2; = p.A609V on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.993); catalogued as COSV53359864; called by muse, mutect2, varscan2
- SORCS2 | c.3295C>T p.L1099F | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV100213734; called by muse, mutect2, varscan2
- SPATA17 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 20/117 reads (17%) | catalogued as COSV65123385; called by muse, mutect2, varscan2
- SPATA7 | c.687T>A p.H229Q | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50418071; called by muse, mutect2, varscan2
- SPDYC | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.651); catalogued as COSV65865361; called by muse, mutect2, varscan2
- SPEM2 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV61603735, COSV61604170; called by muse, mutect2, varscan2
- SPNS1 | c.814A>C p.S272R | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100209262; called by muse, mutect2, varscan2
- SPOCD1 | c.2974C>T p.L992F | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.746); catalogued as COSV57097354; called by muse, mutect2, varscan2
- SRRM2 | c.1687C>T p.H563Y | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as rs1359712457, COSV100071378; called by muse, mutect2, varscan2
- SRRM4 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.033); catalogued as COSV57419476; called by muse, mutect2, varscan2
- STAB1 | c.4866T>A p.D1622E | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.071); catalogued as COSV58738633; called by muse, mutect2, varscan2
- STARD3NL | c.134A>C p.K45T | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.573); catalogued as rs1215281486, COSV50518714; called by muse, mutect2, varscan2
- STAT4 | c.1825T>C p.F609L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV61830700; called by muse, mutect2, varscan2
- STYXL2 | c.3362G>A p.R1121Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.312); catalogued as rs767166518, COSV54806654; called by muse, mutect2, varscan2
- SWT1 | c.2470G>A p.D824N | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62256384; called by muse, mutect2
- SYNPO2L | c.2702C>T p.P901L (on ENST00000394810 / NM_001114133.3; = p.P677L on NM_024875.5) | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV65737688; called by muse, mutect2, varscan2
- TAF1L | c.3026G>A p.G1009E | Missense Mutation (SNP) | VAF 121/253 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54263867; called by muse, mutect2, varscan2
- TAS2R38 | c.829A>T p.I277L | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as COSV71884914, COSV71885639; called by muse, mutect2, varscan2
- TAZ | c.777+1G>T p.X259_splice | Splice Site (SNP) | VAF 57/120 reads (48%) | catalogued as CS115045, COSV54796685; called by muse, mutect2, varscan2
- TBC1D1 | c.1825C>T p.Q609* | Nonsense Mutation (SNP) | VAF 87/168 reads (52%) | catalogued as COSV54721671; called by muse, mutect2, varscan2
- TBC1D8 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV65213650; called by muse, mutect2, varscan2
- TECR | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1166383411, COSV53108480; called by muse, mutect2, varscan2
- TENM3 | c.2980G>A p.E994K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV69311860; called by muse, mutect2, varscan2
- TENM4 | c.3898C>T p.R1300W | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1026919229, COSV53640237; called by muse, mutect2, varscan2
- TEPSIN | c.1394G>A p.W465* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | catalogued as COSV56143464; called by muse, mutect2
- TEX11 | c.1739A>T p.K580M (on ENST00000344304; = p.K565M on NM_031276.3) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60233095; called by muse, mutect2, varscan2
- TEX13A | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs960253897, COSV61148422; called by muse, mutect2, varscan2
- THAP12 | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.496); catalogued as COSV52611258; called by muse, mutect2, varscan2
- THSD7B | c.2884G>A p.G962S | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55703197; called by muse, mutect2, varscan2
- TLN2 | c.4361C>T p.P1454L | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60891344; called by muse, mutect2, varscan2
- TMEM104 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59110168; called by muse, mutect2, varscan2
- TMEM144 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV56701643; called by muse, mutect2, varscan2
- TMEM176A | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV50242184; called by muse, mutect2, varscan2
- TMEM237 | c.760C>T p.Q254* (on ENST00000409883 / NM_001044385.3; = p.Q246* on NM_152388.4) | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV53805400; called by muse, mutect2, varscan2
- TMEM92 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV55946458; called by muse, mutect2, varscan2
- TMPRSS12 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV68256617; called by muse, mutect2, varscan2
- TNFRSF18 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.479); catalogued as COSV60775434; called by muse, mutect2, varscan2
- TNIP3 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1277441435, COSV50249730; called by muse, mutect2, varscan2
- TNIP3 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as COSV50249771; called by muse, mutect2, varscan2
- TOPORS | c.2486C>T p.S829L | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.69); PolyPhen benign (0.376); catalogued as COSV62117335; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558048697, COSV54870223; called by muse, mutect2, varscan2
- TP53BP1 | c.2912G>A p.G971E | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99781372; called by muse, varscan2
- TPX2 | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1461939829, COSV55920411; called by muse, mutect2, varscan2
- TRAF3 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.332); catalogued as rs752493174, COSV61026039; called by muse, mutect2, varscan2
- TRAPPC10 | c.2998C>T p.P1000S | Missense Mutation (SNP) | VAF 78/181 reads (43%) | SIFT tolerated (0.76); PolyPhen benign (0.014); catalogued as COSV52378639; called by muse, mutect2, varscan2
- TRAPPC9 | c.826C>T p.L276F | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.548); catalogued as COSV66902722; called by muse, mutect2, varscan2
- TRHR | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750099981, COSV61234124, COSV61234973; called by muse, mutect2, varscan2
- TRIM58 | c.1111G>A p.G371R | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63571049, COSV63572027; called by muse, mutect2, varscan2
- TRPM8 | c.317T>A p.I106N | Missense Mutation (SNP) | VAF 62/307 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV61222579; called by muse, mutect2, varscan2
- TRPV5 | c.1781G>A p.R594K | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV54687171; called by muse, mutect2, varscan2
- TSKS | c.910G>A p.G304R | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV99883642; called by muse, mutect2, varscan2
- TSKS | c.909G>A p.W303* | Nonsense Mutation (SNP) | VAF 31/86 reads (36%) | catalogued as COSV55872679; called by muse, mutect2, varscan2
- TSPAN12 | c.147G>A p.T49= | Splice Region (SNP) | VAF 24/76 reads (32%) | catalogued as rs746696379, COSV56078681; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTLL7 | c.2293C>T p.R765W | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755453431, COSV53085777; called by muse, mutect2, varscan2
- TTN | c.50287G>A p.G16763R (on ENST00000591111; = p.G9339R on NM_003319.4) | Missense Mutation (SNP) | VAF 53/170 reads (31%) | PolyPhen probably damaging (1); catalogued as COSV60151189; called by muse, mutect2, varscan2
- TTN | c.13690G>A p.E4564K (on ENST00000591111; = p.E3637K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | PolyPhen possibly damaging (0.814); catalogued as rs756371735, COSV60105317, COSV60151214, COSV60366432; called by muse, mutect2, varscan2
- UGT2B17 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 65/139 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV58501062; called by muse, mutect2, varscan2
- UNC5CL | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.156); catalogued as rs1225607529, COSV55110581, COSV55111792; called by muse, mutect2, varscan2
- USP47 | c.1281A>T p.K427N (on ENST00000399455 / NM_001372095.1; = p.K339N on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.143); catalogued as COSV100359388, COSV60465142; called by muse, mutect2, varscan2
- UTRN | c.2527-1G>A p.X843_splice | Splice Site (SNP) | VAF 13/32 reads (41%) | catalogued as COSV62339256; called by muse, mutect2, varscan2
- UXT | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as COSV60039631; called by muse, mutect2, varscan2
- VAT1L | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.038); catalogued as COSV56822322; called by muse, mutect2, varscan2
- VRTN | c.1369T>C p.S457P | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV56441912; called by muse, mutect2, varscan2
- VWA7 | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV65172912; called by muse, mutect2, varscan2
- WDR19 | c.269G>A p.S90N | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs761275061, COSV56466717; called by muse, mutect2, varscan2
- WDR59 | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1462496551, COSV50937337; called by muse, mutect2, varscan2
- WHRN | c.838-2A>T p.X280_splice | Splice Site (SNP) | VAF 86/173 reads (50%) | catalogued as COSV54332055; called by muse, mutect2, varscan2
- WWP1 | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55360672; called by muse, mutect2, varscan2
- XIRP2 | c.991C>T p.H331Y (on ENST00000628543; = p.H506Y on NM_152381.6) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54701101; called by muse, mutect2, varscan2
- XPC | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1559380899, COSV53205816; called by muse, mutect2, varscan2
- XPO6 | c.1718G>A p.G573E | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV100485317, COSV58968949; called by muse, mutect2, varscan2
- XPO6 | c.1717G>A p.G573R | Missense Mutation (SNP) | VAF 75/212 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs778942589, COSV58969735; called by muse, mutect2, varscan2
- ZFHX3 | c.3455C>T p.A1152V | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV51723402, COSV99215453; called by muse, mutect2, varscan2
- ZFP2 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV63725376, COSV63725784; called by muse, mutect2, varscan2
- ZFPM2 | c.2435C>T p.S812F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV65874392; called by muse, mutect2
- ZNF106 | c.1393C>T p.Q465* | Nonsense Mutation (SNP) | VAF 51/277 reads (18%) | catalogued as COSV55518106; called by muse, mutect2, varscan2
- ZNF16 | c.1906A>G p.K636E | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767550356, COSV52764369; called by muse, mutect2, varscan2
- ZNF160 | c.2447C>T p.P816L | Missense Mutation (SNP) | VAF 48/307 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as COSV100762462; called by muse, mutect2, varscan2
- ZNF160 | c.2446C>T p.P816S | Missense Mutation (SNP) | VAF 48/309 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as COSV100762463; called by muse, mutect2, varscan2
- ZNF211 | c.893C>T p.S298F (on ENST00000347302 / NM_198855.4; = p.S311F on NM_006385.5) | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.598); catalogued as COSV53743191; called by muse, mutect2, varscan2
- ZNF225 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV53472069; called by muse, mutect2, varscan2
- ZNF285 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.851); catalogued as COSV58409581; called by muse, mutect2, varscan2
- ZNF385B | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61175752; called by muse, mutect2, varscan2
- ZNF420 | c.1025G>A p.R342K | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58494735; called by muse, mutect2, varscan2
- ZNF423 | c.853G>A p.E285K (on ENST00000563137 / NM_001379286.1; = p.E277K on NM_015069.4) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as rs1313395769, COSV52191771; called by muse, mutect2, varscan2
- ZNF43 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV61684479; called by muse, mutect2, varscan2
- ZNF443 | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 33/103 reads (32%) | catalogued as COSV56892478, COSV56892688; called by muse, mutect2, varscan2
- ZNF518A | c.2518C>T p.P840S | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1554885163, COSV60151870; called by muse, mutect2, varscan2
- ZNF536 | c.1075T>C p.F359L | Missense Mutation (SNP) | VAF 65/307 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62819567; called by muse, mutect2, varscan2
- ZNF555 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.051); catalogued as COSV62073380; called by muse, mutect2, varscan2
- ZNF573 | c.1900G>T p.G634C (on ENST00000536220 / NM_001172692.1; = p.G576C on NM_152360.3) | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59826247; called by muse, mutect2, varscan2
- ZNF792 | c.1892T>C p.V631A | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.018); catalogued as COSV68693686; called by muse, mutect2, varscan2
- ZNF804A | c.2368C>T p.H790Y | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs578257332, COSV56435674; called by muse, mutect2, varscan2
- ZNF827 | c.2452C>T p.P818S | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV65228749; called by muse, mutect2, varscan2
- ZNF98 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV63337543, COSV63340764; called by muse, mutect2, varscan2
- ZNFX1 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 97/366 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as COSV65576438; called by muse, mutect2, varscan2
- CHORDC1 | c.18del p.Y6* | Frame Shift Del (DEL) | VAF 15/92 reads (16%) | called by mutect2, pindel, varscan2
- IGHV1-2 | c.297_310del p.Y99* | Nonsense Mutation (DEL) | VAF 89/293 reads (30%) | called by mutect2, pindel, varscan2
- IGKV1-9 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 90/347 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- IGKV3D-11 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MARK1 | c.825del p.I276Ffs*13 | Frame Shift Del (DEL) | VAF 40/120 reads (33%) | called by mutect2, pindel, varscan2
- NPAS3 | c.1372dup p.S458Ffs*8 (on ENST00000356141 / NM_001164749.2; = p.S426Ffs*8 on NM_022123.3) | Frame Shift Ins (INS) | VAF 32/192 reads (17%) | called by mutect2, pindel, varscan2
- PANK1 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by mutect2, varscan2
- PRAMEF15 | c.132G>T p.E44D | Missense Mutation (SNP) | VAF 42/272 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- PRH2 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- PUS10 | c.1552-20_1555del p.X518_splice | Splice Site (DEL) | VAF 48/198 reads (24%) | called by mutect2, pindel
- SGSM1 | c.519del p.L173Ffs*8 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | called by mutect2, pindel, varscan2
- SPANXB1 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 38/481 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- TGM5 | c.2126del p.K709Rfs*8 (on ENST00000220420 / NM_201631.4; = p.K627Rfs*8 on NM_004245.4) | Frame Shift Del (DEL) | VAF 23/63 reads (37%) | called by mutect2, pindel, varscan2
- TRAV9-1 | c.241T>A p.F81I | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- A2ML1 | c.3601T>C p.L1201= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as COSV55293045; called by muse, varscan2
- A2ML1 | c.3699G>A p.G1233= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV55291603, COSV55293055; called by muse, varscan2
- ABCA13 | c.3684C>T p.F1228= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV70032842; called by muse, mutect2, varscan2
- ABCA8 | c.4389A>G p.Q1463= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV52204573; called by muse, mutect2, varscan2
- ABCG4 | c.1878C>T p.F626= | Silent (SNP) | VAF 31/122 reads (25%) | catalogued as COSV56644091; called by muse, mutect2, varscan2
- ACKR1 | c.33C>T p.S11= | Silent (SNP) | VAF 12/145 reads (8%) | catalogued as COSV63673722; called by muse, mutect2
- ACTG1 | c.321G>A p.E107= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV59510938; called by muse, mutect2, varscan2
- ACTG2 | c.102C>T p.S34= | Silent (SNP) | VAF 37/141 reads (26%) | catalogued as rs978896811, COSV61828791; called by muse, mutect2, varscan2
- ACTL9 | c.1159C>T p.L387= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as COSV61005505; called by muse, mutect2, varscan2
- ADAMTS15 | c.84C>T p.P28= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV54507188; called by muse, mutect2, varscan2
- ADCY8 | c.1728C>T p.F576= | Silent (SNP) | VAF 89/254 reads (35%) | catalogued as COSV53901355, COSV53906242; called by muse, mutect2, varscan2
- ADGRF2 | c.2067G>A p.Q689= (on ENST00000296862 / NM_001368115.2; = p.Q621= on NM_153839.7) | Silent (SNP) | VAF 51/84 reads (61%) | catalogued as COSV57288619, COSV57289283; called by muse, mutect2, varscan2
- ADGRL3 | c.1533C>T p.T511= (on ENST00000506720 / NM_001322402.2; = p.T443= on NM_015236.6) | Silent (SNP) | VAF 27/401 reads (7%) | catalogued as COSV72229116, COSV72231000; called by muse, mutect2
- AFF3 | c.687G>A p.Q229= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as COSV57848756; called by muse, mutect2, varscan2
- AMZ1 | c.1284G>A p.V428= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV56685211; called by muse, mutect2, varscan2
- ANGPTL5 | c.867C>A p.L289= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV57533516; called by muse, mutect2
- ANO2 | c.786C>T p.I262= (on ENST00000356134 / NM_001278597.3; = p.I266= on NM_001278596.3) | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV59029500; called by muse, mutect2, varscan2
- AP2A2 | c.2481C>T p.F827= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV59961556; called by muse, mutect2, varscan2
- APLP2 | c.2019C>T p.G673= | Silent (SNP) | VAF 28/119 reads (24%) | catalogued as rs746436295, COSV99600027; called by muse, mutect2, varscan2
- APOBEC2 | c.135A>G p.E45= | Silent (SNP) | VAF 68/117 reads (58%) | catalogued as COSV55142947; called by muse, mutect2, varscan2
- ASTN2 | c.2307C>T p.F769= (on ENST00000313400 / NM_001365069.1; = p.F718= on NM_014010.5) | Silent (SNP) | VAF 93/213 reads (44%) | catalogued as rs1428077433, COSV57752242; called by muse, mutect2, varscan2
- ATP13A5 | c.2943C>T p.S981= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV60871087; called by muse, mutect2, varscan2
- ATP13A5 | c.246T>C p.F82= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV60871095; called by muse, mutect2, varscan2
- ATP1A3 | c.660C>T p.S220= (on ENST00000545399 / NM_001256214.2; = p.S207= on NM_152296.5) | Silent (SNP) | VAF 30/181 reads (17%) | catalogued as COSV57488704; called by muse, mutect2, varscan2
- ATP2C2 | c.2382G>A p.R794= | Silent (SNP) | VAF 109/217 reads (50%) | catalogued as rs775248461, COSV52296191; called by muse, mutect2, varscan2
- ATP6V0A1 | c.984C>T p.T328= | Silent (SNP) | VAF 38/171 reads (22%) | catalogued as rs753296379, COSV52874760; called by muse, mutect2, varscan2
- ATP8B4 | c.2763C>T p.A921= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV52718231; called by muse, mutect2, varscan2
- AURKC | c.201C>T p.F67= (on ENST00000302804 / NM_001015878.2; = p.F33= on NM_003160.3) | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs747153965, COSV57139046; called by muse, mutect2, varscan2
- BFSP1 | c.1443C>T p.D481= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV64900764; called by muse, mutect2, varscan2
- BICD1 | c.2064C>T p.I688= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as rs139652205, COSV55681745; called by muse, mutect2, varscan2
- BLK | c.1041G>A p.G347= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs1475104158, COSV52053360; called by muse, mutect2, varscan2
- BPIFB4 | c.1332C>T p.I444= | Silent (SNP) | VAF 68/187 reads (36%) | catalogued as rs376117181; called by muse, mutect2, varscan2
- BRS3 | c.990C>T p.L330= | Silent (SNP) | VAF 39/270 reads (14%) | catalogued as COSV65711123; called by muse, mutect2, varscan2
- BUD13 | c.732C>T p.V244= | Silent (SNP) | VAF 53/311 reads (17%) | catalogued as rs770238071, COSV52768856; called by muse, mutect2, varscan2
- C4orf17 | c.1017G>A p.R339= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs776667824, COSV56745386; called by muse, mutect2, varscan2
- CACNA2D4 | c.879G>A p.V293= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV54952808; called by muse, mutect2, varscan2
- CBLIF | c.1119C>T p.I373= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV57239388; called by muse, mutect2, varscan2
- CCDC87 | c.2397C>T p.I799= | Silent (SNP) | VAF 105/395 reads (27%) | catalogued as COSV59579559; called by muse, mutect2, varscan2
- CCL23 | c.48C>T p.A16= | Silent (SNP) | VAF 24/82 reads (29%) | called by muse, mutect2, varscan2
- CD163 | c.2892G>A p.Q964= | Silent (SNP) | VAF 44/130 reads (34%) | catalogued as rs753020548, COSV63134101; called by muse, mutect2, varscan2
- CD163 | c.2073C>T p.S691= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as COSV63134119; called by muse, mutect2, varscan2
- CDH8 | c.1260C>A p.I420= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs367989208, COSV54860822; called by muse, mutect2, varscan2
- CDYL2 | c.1029C>T p.I343= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV73654327; called by muse, mutect2, varscan2
- CLEC16A | c.2973T>A p.I991= | Silent (SNP) | VAF 39/202 reads (19%) | catalogued as COSV55490329; called by muse, mutect2, varscan2
- COL4A4 | c.1350G>A p.Q450= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as COSV61633514; called by muse, mutect2, varscan2
- CPA2 | c.651C>T p.L217= | Silent (SNP) | VAF 84/252 reads (33%) | catalogued as rs1324937145, COSV55980040; called by muse, mutect2
- CPNE9 | c.834C>A p.L278= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV56068957; called by muse, mutect2, varscan2
- CSMD1 | c.8283G>A p.V2761= (on ENST00000520002; = p.V2760= on NM_033225.6) | Silent (SNP) | VAF 62/174 reads (36%) | catalogued as COSV59340736; called by muse, mutect2, varscan2
- CSMD3 | c.4878C>T p.I1626= (on ENST00000297405 / NM_001363185.1; = p.I1522= on NM_052900.3) | Silent (SNP) | VAF 34/173 reads (20%) | catalogued as COSV52220862; called by muse, mutect2, varscan2
- CTNNBL1 | c.1614G>A p.E538= | Silent (SNP) | VAF 48/131 reads (37%) | catalogued as COSV63745509; called by muse, mutect2, varscan2
- CYB561A3 | c.261C>T p.H87= | Silent (SNP) | VAF 44/157 reads (28%) | catalogued as COSV53652485; called by muse, mutect2, varscan2
- CYP1A1 | c.265C>T p.L89= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as rs994552466, COSV101122365, COSV101122375; called by muse, mutect2, varscan2
- CYP1A1 | c.264C>T p.G88= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV101122376; called by muse, mutect2, varscan2
- DAPK2 | c.165G>A p.K55= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs763131157, COSV56046354; called by muse, mutect2, varscan2
- DDIT4L | c.507C>T p.I169= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV56767574; called by muse, mutect2, varscan2
- DDO | c.384C>T p.P128= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV64470257; called by muse, mutect2, varscan2
- DDX10 | c.918C>T p.S306= | Silent (SNP) | VAF 82/284 reads (29%) | catalogued as COSV59436526; called by muse, mutect2, varscan2
- DDX28 | c.709C>T p.L237= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV60105858; called by muse, mutect2, varscan2
- DENND5A | c.2589C>T p.S863= | Silent (SNP) | VAF 36/195 reads (18%) | catalogued as COSV100064779, COSV60238213; called by muse, mutect2, varscan2
- DEUP1 | c.1635A>T p.P545= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as COSV53213446; called by muse, mutect2, varscan2
- DHCR7 | c.1371G>A p.R457= | Silent (SNP) | VAF 69/197 reads (35%) | catalogued as COSV62795697; called by muse, mutect2, varscan2
- DOCK10 | c.5808C>T p.N1936= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs374596718; called by muse, mutect2, varscan2
- DOCK11 | c.291G>A p.Q97= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV52241294, COSV52241823; called by muse, mutect2, varscan2
- DOP1B | c.1452C>T p.F484= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV101215777; called by muse, mutect2, varscan2
- DOP1B | c.1453C>T p.L485= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV101215779; called by muse, mutect2, varscan2
- DPYS | c.1284C>T p.F428= | Silent (SNP) | VAF 35/202 reads (17%) | catalogued as rs769020409, COSV60907786; called by muse, mutect2, varscan2
- DSCAM | c.3609C>T p.S1203= | Silent (SNP) | VAF 62/153 reads (41%) | catalogued as COSV68029671; called by muse, mutect2, varscan2
- DSN1 | c.201C>T p.L67= | Silent (SNP) | VAF 38/149 reads (26%) | catalogued as COSV65518850, COSV65519509; called by muse, mutect2, varscan2
- DTX3 | c.141C>T p.S47= | Silent (SNP) | VAF 154/379 reads (41%) | catalogued as COSV54087659; called by muse, mutect2, varscan2
- DVL3 | c.1461C>T p.S487= | Silent (SNP) | VAF 99/272 reads (36%) | catalogued as rs756254669, COSV57456878; called by muse, mutect2, varscan2
- EDC4 | c.723C>T p.I241= | Silent (SNP) | VAF 31/214 reads (14%) | catalogued as rs1468124897, COSV62766591; called by muse, mutect2
- EFCAB3 | c.495C>T p.F165= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV59502873; called by muse, mutect2
- ELF4 | c.1908C>T p.S636= | Silent (SNP) | VAF 50/310 reads (16%) | catalogued as COSV100257567, COSV57453582; called by muse, varscan2
- ELMO3 | c.180G>A p.V60= (on ENST00000652269; = p.V7= on NM_024712.5) | Silent (SNP) | VAF 60/176 reads (34%) | catalogued as COSV62606947; called by muse, mutect2
- EMP2 | c.60C>T p.F20= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV59821544; called by mutect2, varscan2
- ENO3 | c.609T>C p.D203= | Silent (SNP) | VAF 52/124 reads (42%) | catalogued as COSV52777873; called by muse, mutect2, varscan2
- EPB41L1 | c.1284C>T p.S428= | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as rs767889507, COSV52439576; called by muse, mutect2, varscan2
- ERC2 | c.54C>T p.S18= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs773009368, COSV55634274; called by muse, mutect2, varscan2
- ERCC6L | c.1260G>A p.R420= | Silent (SNP) | VAF 21/162 reads (13%) | catalogued as COSV57821056; called by muse, mutect2, varscan2
- EYA2 | c.876C>T p.S292= | Silent (SNP) | VAF 118/373 reads (32%) | catalogued as rs1568776114, COSV57942084; called by muse, mutect2, varscan2
- F8 | c.5991C>T p.L1997= | Silent (SNP) | VAF 30/211 reads (14%) | catalogued as COSV64275009; called by muse, mutect2, varscan2
- F8 | c.2712G>A p.L904= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV64275016; called by muse, mutect2, varscan2
- FAM193B | c.1038C>T p.L346= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV61558060; called by muse, mutect2, varscan2
- FAM47C | c.648G>A p.E216= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as COSV63727687; called by muse, mutect2, varscan2
- FANCA | c.2676C>T p.S892= | Silent (SNP) | VAF 41/106 reads (39%) | catalogued as rs756478412, COSV59797165; called by muse, mutect2, varscan2
- FANCB | c.2418G>A p.R806= | Silent (SNP) | VAF 25/126 reads (20%) | catalogued as COSV60760537; called by muse, mutect2, varscan2
- FANCB | c.2262C>T p.F754= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV60760547; called by muse, mutect2, varscan2
- FAT3 | c.6528C>T p.I2176= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV53131009; called by muse, mutect2, varscan2
- FAT3 | c.10572G>A p.K3524= | Silent (SNP) | VAF 122/373 reads (33%) | catalogued as COSV53131038; called by muse, mutect2, varscan2
- FBXL19 | c.1011G>A p.S337= | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as rs768420902, COSV57943360; called by muse, mutect2, varscan2
- FGF23 | c.561G>A p.R187= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV52976702; called by muse, mutect2, varscan2
- FMR1NB | c.411G>A p.R137= | Silent (SNP) | VAF 28/166 reads (17%) | catalogued as COSV63272826; called by muse, mutect2
- FNDC3B | c.387C>T p.H129= | Silent (SNP) | VAF 71/416 reads (17%) | catalogued as COSV100394666, COSV61044648; called by muse, mutect2, varscan2
- FPR2 | c.984C>T p.D328= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV60673291; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.495G>A p.Q165= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV61323162; called by muse, mutect2, varscan2
- GLCCI1 | c.1437C>T p.N479= | Silent (SNP) | VAF 84/562 reads (15%) | catalogued as COSV56202844; called by muse, mutect2
- GMIP | c.1491G>A p.R497= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as COSV52557482; called by muse, mutect2, varscan2
- GPC5 | c.1150A>C p.R384= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV65607477; called by muse, mutect2, varscan2
- GPC6 | c.615G>A p.R205= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV65513298; called by muse, mutect2, varscan2
- GRIA3 | c.57C>A p.V19= | Silent (SNP) | VAF 45/231 reads (19%) | catalogued as rs896354134, COSV52067725; called by muse, mutect2, varscan2
- GRM7 | c.1395G>A p.V465= | Silent (SNP) | VAF 38/166 reads (23%) | catalogued as COSV63149944; called by muse, mutect2, varscan2
- GRM8 | c.2121C>T p.L707= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV58808928; called by muse, mutect2, varscan2
- HAL | c.357C>T p.D119= | Silent (SNP) | VAF 63/349 reads (18%) | catalogued as rs1440136549, COSV54118594; called by muse, mutect2, varscan2
- HHATL | c.1503G>A p.E501= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV55132706, COSV55135291; called by muse, mutect2, varscan2
- HIC2 | c.1596C>T p.P532= | Silent (SNP) | VAF 52/226 reads (23%) | catalogued as rs748771345, COSV68042437; called by muse, mutect2, varscan2
- HOXD13 | c.540C>T p.A180= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as COSV66832710; called by muse, mutect2, varscan2
- HSPG2 | c.11346C>T p.T3782= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV101013548; called by muse, mutect2
- HTRA4 | c.1287C>T p.H429= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs576647651, COSV56759861; called by muse, mutect2, varscan2
- HUWE1 | c.1425C>T p.I475= | Silent (SNP) | VAF 46/248 reads (19%) | catalogued as COSV53351541; called by muse, mutect2, varscan2
- IL36RN | c.309G>A p.R103= | Silent (SNP) | VAF 28/132 reads (21%) | catalogued as rs149664037; called by muse, mutect2, varscan2
- IQCF1 | c.459C>T p.I153= | Silent (SNP) | VAF 69/253 reads (27%) | catalogued as COSV58823658; called by muse, mutect2, varscan2
- ITGB4 | c.504T>C p.T168= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as COSV52328518; called by muse, mutect2, varscan2
- JPT2 | c.231C>T p.P77= | Silent (SNP) | VAF 33/124 reads (27%) | catalogued as rs1242071945, COSV50189030; called by muse, mutect2, varscan2
- KCNS3 | c.309C>T p.I103= | Silent (SNP) | VAF 74/202 reads (37%) | catalogued as rs141345709; called by muse, mutect2, varscan2
- KIFAP3 | c.1059A>C p.I353= | Silent (SNP) | VAF 23/154 reads (15%) | catalogued as COSV63034570, COSV63034966; called by muse, mutect2, varscan2
- KLHL1 | c.2091C>T p.L697= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as COSV64775120; called by muse, mutect2, varscan2
- KMT2A | c.6624G>A p.R2208= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV63287884; called by muse, mutect2, varscan2
- KRI1 | c.718C>T p.L240= | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as rs1382999476, COSV57265054; called by muse, mutect2, varscan2
- KRT17 | c.174C>T p.S58= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs1439878157, COSV100245240; called by muse, mutect2, varscan2
- KRT74 | c.540G>A p.L180= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as COSV59772197; called by muse, mutect2, varscan2
- L1CAM | c.3264C>T p.I1088= | Silent (SNP) | VAF 55/265 reads (21%) | catalogued as COSV62828693; called by muse, mutect2, varscan2
- LAMB4 | c.3045C>T p.L1015= | Silent (SNP) | VAF 119/375 reads (32%) | catalogued as COSV52722558; called by muse, mutect2, varscan2
- LMF1 | c.1110G>A p.S370= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs370181310; called by mutect2, varscan2
- LRIG1 | c.276G>A p.P92= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs771914650, COSV56242299; called by muse, mutect2, varscan2
- LRRC59 | c.873A>T p.L291= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV56814841; called by muse, mutect2, varscan2
- LRRTM1 | c.1482G>A p.P494= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV54443255, COSV54443591; called by muse, mutect2, varscan2
- MAGEA11 | c.1050C>T p.F350= | Silent (SNP) | VAF 48/376 reads (13%) | catalogued as COSV60756674; called by muse, mutect2, varscan2
- MAGEC3 | c.1788C>T p.I596= | Silent (SNP) | VAF 28/169 reads (17%) | catalogued as rs1402686369, COSV53580624; called by muse, mutect2, varscan2
- MAST2 | c.4890T>G p.L1630= | Silent (SNP) | VAF 44/155 reads (28%) | catalogued as COSV53108582; called by muse, mutect2, varscan2
- MCTP1 | c.1029C>T p.A343= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as rs142378017; called by muse, mutect2, varscan2
- ME1 | c.696T>A p.V232= | Silent (SNP) | VAF 44/84 reads (52%) | catalogued as COSV63840299; called by muse, mutect2, varscan2
- MED13L | c.81C>T p.L27= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV56123134; called by muse, mutect2, varscan2
- MICAL3 | c.1881C>T p.L627= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs377379411, COSV52899402; called by muse, mutect2, varscan2
- MICALL2 | c.363C>T p.A121= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs961127095, COSV52516578; called by muse, mutect2
- MPL | c.1176C>T p.P392= | Silent (SNP) | VAF 57/294 reads (19%) | catalogued as rs757289947, COSV65245359; called by muse, mutect2, varscan2
- MSH3 | c.3355C>T p.L1119= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as rs1396664221, COSV54155251, COSV99035295; called by muse, mutect2, varscan2
- MSRA | c.123G>A p.K41= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV57804921; called by muse, mutect2, varscan2
- MUC16 | c.26136G>A p.E8712= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV67475693; called by muse, mutect2, varscan2
- MUC17 | c.4716C>T p.S1572= | Silent (SNP) | VAF 91/550 reads (17%) | catalogued as COSV60292954; called by muse, mutect2, varscan2
- MYH1 | c.4263G>A p.T1421= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as rs370946637; called by muse, mutect2, varscan2
- MYH4 | c.4824G>A p.E1608= | Silent (SNP) | VAF 102/197 reads (52%) | catalogued as COSV55120713; called by muse, mutect2, varscan2
- MYO18A | c.3813G>A p.E1271= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV62868772; called by muse, mutect2, varscan2
- NAPSA | c.525C>T p.S175= | Silent (SNP) | VAF 35/192 reads (18%) | catalogued as COSV53798051; called by muse, mutect2, varscan2
- NINL | c.2112C>T p.P704= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as rs146085894; called by muse, mutect2, varscan2
- NIPBL | c.8133C>T p.I2711= | Silent (SNP) | VAF 45/197 reads (23%) | catalogued as rs780857060, COSV56956125; called by muse, mutect2, varscan2
- NLRP3 | c.894C>T p.L298= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as COSV60226842; called by muse, mutect2, varscan2
- NPSR1 | c.468C>T p.F156= | Silent (SNP) | VAF 76/215 reads (35%) | catalogued as COSV62196839; called by muse, mutect2, varscan2
- NSFL1C | c.60G>A p.E20= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1033104224, COSV99401588; called by muse, mutect2, varscan2
- NUF2 | c.1002G>A p.L334= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs758647956, COSV54844557; called by muse, mutect2, varscan2
- OR10X1 | c.534G>A p.L178= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV63767533; called by muse, mutect2, varscan2
- OR2A12 | c.132C>T p.I44= | Silent (SNP) | VAF 58/201 reads (29%) | catalogued as COSV68821097; called by muse, mutect2, varscan2
- OR2AT4 | c.666C>T p.S222= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs868638069, COSV100532417, COSV59407181; called by muse, varscan2
- OR2AT4 | c.603C>G p.T201= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100532396; called by muse, varscan2
- OR2F2 | c.54C>T p.S18= | Silent (SNP) | VAF 84/307 reads (27%) | catalogued as COSV68832955; called by muse, mutect2, varscan2
- OR52A5 | c.585C>A p.I195= | Silent (SNP) | VAF 48/188 reads (26%) | catalogued as rs777752079, COSV100263555; called by muse, mutect2, varscan2
- OR52M1 | c.351C>T p.F117= | Silent (SNP) | VAF 53/155 reads (34%) | catalogued as rs535039305, COSV64172213; called by muse, mutect2, varscan2
- OR5A1 | c.483C>T p.I161= | Silent (SNP) | VAF 167/488 reads (34%) | catalogued as COSV57377074; called by muse, mutect2, varscan2
- OR5AK2 | c.615T>A p.S205= | Silent (SNP) | VAF 101/316 reads (32%) | catalogued as COSV58804729; called by muse, mutect2, varscan2
- OR5B2 | c.900G>A p.K300= | Silent (SNP) | VAF 35/105 reads (33%) | catalogued as COSV56908685; called by muse, mutect2, varscan2
- OR6F1 | c.858C>T p.N286= | Silent (SNP) | VAF 61/178 reads (34%) | catalogued as COSV100129412; called by muse, mutect2, varscan2
- OR6X1 | c.558C>T p.A186= | Silent (SNP) | VAF 19/164 reads (12%) | catalogued as COSV60009997; called by muse, mutect2, varscan2
- P3H3 | c.927C>T p.F309= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs782408611; called by muse, mutect2
- PARVG | c.735C>A p.L245= | Silent (SNP) | VAF 47/317 reads (15%) | catalogued as COSV63562072; called by muse, mutect2, varscan2
- PCARE | c.2580G>A p.K860= | Silent (SNP) | VAF 47/144 reads (33%) | catalogued as rs1248007781, COSV59055612; called by muse, mutect2, varscan2
- PCDH1 | c.2808C>T p.S936= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs765660375, COSV54615575; called by muse, mutect2, varscan2
- PCDHB5 | c.1584C>T p.F528= | Silent (SNP) | VAF 42/78 reads (54%) | catalogued as COSV50651148; called by muse, mutect2, varscan2
- PCDHB5 | c.2295C>T p.F765= | Silent (SNP) | VAF 111/225 reads (49%) | catalogued as COSV50647696, COSV50656695; called by muse, mutect2, varscan2
- PCLO | c.10125C>T p.T3375= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs553676793, COSV61644241; called by muse, mutect2, varscan2
- PCSK1 | c.1035G>A p.E345= | Silent (SNP) | VAF 119/301 reads (40%) | catalogued as rs955247107, COSV60736118; called by muse, mutect2, varscan2
- PFKFB4 | c.981C>T p.I327= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs745445999, COSV51681580; called by muse, mutect2, varscan2
- PHACTR3 | c.837G>A p.P279= | Silent (SNP) | VAF 26/137 reads (19%) | catalogued as rs146810775; called by muse, mutect2, varscan2
- PITPNM3 | c.1848C>T p.P616= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs747737646, COSV99338969; called by muse, mutect2, varscan2
- PLA2G2A | c.36C>T p.I12= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs148271639, COSV64287340; called by muse, mutect2, varscan2
- PLCB4 | c.2376C>T p.L792= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV53806284; called by muse, mutect2, varscan2
- PLEKHM1 | c.2214C>T p.T738= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs898831998; called by mutect2, varscan2
- PLIN4 | c.1896G>A p.K632= (on ENST00000301286; = p.K647= on NM_001367868.2) | Silent (SNP) | VAF 57/191 reads (30%) | catalogued as COSV56693319; called by muse, mutect2, varscan2
- PMS2 | c.1500C>T p.S500= | Silent (SNP) | VAF 59/161 reads (37%) | catalogued as rs116094787; ClinVar: likely benign; called by muse, mutect2, varscan2
- PNPLA7 | c.3078C>T p.I1026= | Silent (SNP) | VAF 97/211 reads (46%) | catalogued as rs1303018271, COSV53000979, COSV53002464; called by muse, mutect2, varscan2
- POLD3 | c.612C>T p.T204= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV55243663; called by muse, mutect2, varscan2
- POLE | c.4485C>T p.A1495= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as rs878854872, COSV57683507; called by muse, mutect2, varscan2
- PRAMEF15 | c.474G>A p.K158= | Silent (SNP) | VAF 67/1322 reads (5%) | called by muse, mutect2
- PRICKLE1 | c.1923G>A p.G641= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV58207975; called by muse, mutect2, varscan2
- PRKCSH | c.1020G>A p.P340= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs754020641, COSV52950877; called by muse, mutect2, varscan2
- RAB37 | c.267G>A p.Q89= (on ENST00000392613 / NM_001006638.3; = p.Q82= on NM_175738.5) | Silent (SNP) | VAF 38/181 reads (21%) | catalogued as COSV61195564; called by muse, mutect2, varscan2
- REG3A | c.111G>A p.R37= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV59410181; called by muse, mutect2, varscan2
- RIC1 | c.1923C>T p.F641= | Silent (SNP) | VAF 115/222 reads (52%) | catalogued as COSV52611327; called by muse, mutect2, varscan2
- RPH3A | c.1890G>A p.L630= (on ENST00000389385 / NM_001143854.2; = p.L626= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as COSV101231888, COSV66991736; called by muse, mutect2, varscan2
- RYR2 | c.819C>T p.S273= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as rs746461178, COSV100772837, COSV63693234; ClinVar: likely benign; called by muse, mutect2, varscan2
- RYR3 | c.8055G>A p.V2685= (on ENST00000389232; = p.V2686= on NM_001036.6) | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as rs905457147, COSV66796498; called by muse, mutect2, varscan2
- S100A7L2 | c.264G>A p.K88= | Silent (SNP) | VAF 52/231 reads (23%) | catalogued as COSV64195289; called by muse, mutect2, varscan2
- SCEL | c.1758G>A p.E586= (on ENST00000349847 / NM_144777.3; = p.E566= on NM_003843.4) | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs769294817, COSV62993859; called by muse, mutect2, varscan2
- SCN5A | c.564C>T p.F188= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs878855943, COSV61129118; called by muse, mutect2, varscan2
- SCN7A | c.69G>A p.Q23= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV69269315, COSV69270901; called by muse, mutect2
- SEMG1 | c.294A>G p.R98= | Silent (SNP) | VAF 77/186 reads (41%) | catalogued as COSV99725519; called by muse, mutect2, varscan2
- SEPTIN1 | c.549C>T p.C183= (on ENST00000321367; = p.C136= on NM_052838.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/193 reads (17%) | catalogued as rs1426220846, COSV58442694; called by muse, mutect2, varscan2
- SERPINE3 | c.264G>A p.R88= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as COSV68545530; called by muse, mutect2, varscan2
- SGSM1 | c.2892C>T p.I964= (on ENST00000400359 / NM_001039948.4; = p.I903= on NM_133454.3) | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV63082552; called by muse, mutect2, varscan2
- SH2D3A | c.111T>G p.V37= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV55586360; called by muse, mutect2, varscan2
- SHMT2 | c.1032C>T p.T344= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as COSV61074432; called by muse, mutect2, varscan2
- SHROOM2 | c.2100C>T p.R700= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV66611082; called by mutect2, varscan2
- SIDT2 | c.1929C>T p.I643= | Silent (SNP) | VAF 81/217 reads (37%) | catalogued as rs1302382764, COSV54057941; called by muse, mutect2, varscan2
- SIGLEC5 | c.1290G>A p.S430= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs1228507057, COSV55780892; called by muse, mutect2
- SKIL | c.1449T>C p.N483= | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as COSV52060555; called by muse, mutect2, varscan2
- SLC25A53 | c.801C>T p.L267= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as rs1360182262, COSV62459577; called by muse, mutect2
- SLC26A4 | c.486C>T p.L162= | Silent (SNP) | VAF 67/223 reads (30%) | catalogued as rs370020280, COSV55917685; called by muse, mutect2, varscan2
- SLC6A11 | c.1851G>A p.K617= | Silent (SNP) | VAF 42/215 reads (20%) | catalogued as COSV54395280; called by muse, mutect2, varscan2
- SLC6A8 | c.1083C>T p.S361= | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as COSV53472588; called by muse, mutect2, varscan2
- SORCS2 | c.3294C>T p.I1098= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs1463055917, COSV100213731; called by muse, mutect2, varscan2
- SPICE1 | c.1633T>C p.L545= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as COSV55622076; called by muse, mutect2, varscan2
- SPRR1B | c.33C>T p.T11= | Silent (SNP) | VAF 110/414 reads (27%) | catalogued as COSV61067479; called by muse, mutect2
- SRPK2 | c.1290C>T p.S430= | Silent (SNP) | VAF 66/228 reads (29%) | catalogued as COSV61962112; called by muse, mutect2, varscan2
- SRRM2 | c.1686C>T p.S562= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV100071377; called by muse, mutect2, varscan2
- SSTR5 | c.672C>T p.I224= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs770171341, COSV53511919; called by muse, mutect2, varscan2
- STAT3 | c.633C>T p.D211= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as COSV52889149; called by muse, mutect2, varscan2
- STEAP3 | c.438C>T p.F146= | Silent (SNP) | VAF 22/214 reads (10%) | catalogued as COSV61529595; called by muse, mutect2, varscan2
- SYNE2 | c.8943C>T p.I2981= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as COSV59955886; called by muse, mutect2, varscan2
- TBC1D16 | c.1197C>T p.S399= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs983029193, COSV60478842; called by muse, mutect2, varscan2
- TCF7L1 | c.837G>A p.S279= | Silent (SNP) | VAF 61/186 reads (33%) | catalogued as rs768261933, COSV56399954; called by muse, mutect2, varscan2
- TEAD4 | c.855C>T p.F285= | Silent (SNP) | VAF 37/221 reads (17%) | catalogued as rs267603437; called by muse, mutect2, varscan2
- TENT5D | c.966C>T p.L322= | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as COSV57637448; called by muse, mutect2, varscan2
- TFRC | c.945C>T p.S315= | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as rs956503134, COSV64055306; called by muse, mutect2, varscan2
- THBS4 | c.2226G>A p.G742= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV63469872; called by muse, mutect2, varscan2
- THSD7B | c.1653C>T p.I551= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV55703176; called by muse, mutect2, varscan2
- TMEM132A | c.1377C>T p.A459= (on ENST00000453848 / NM_178031.3; = p.A460= on NM_017870.4) | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs765219109, COSV50000273; called by muse, mutect2, varscan2
- TMEM200A | c.483G>A p.R161= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV51654922, COSV51660242; called by muse, mutect2, varscan2
- TMEM255B | c.363G>A p.T121= | Silent (SNP) | VAF 34/65 reads (52%) | catalogued as rs369542516; called by muse, mutect2, varscan2
- TNXB | c.4995T>C p.V1665= (on ENST00000647633; = p.V1418= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 132/242 reads (55%) | catalogued as COSV64481464; called by muse, varscan2
- TNXB | c.4893C>T p.S1631= (on ENST00000647633; = p.S1384= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 98/159 reads (62%) | catalogued as rs1447500507, COSV64481546; called by muse, varscan2
- TP53BP1 | c.2913A>C p.G971= | Silent (SNP) | VAF 25/157 reads (16%) | catalogued as COSV99781370; called by muse, mutect2, varscan2
- TRBV2 | c.237A>T p.I79= | Silent (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- TRPM5 | c.2658C>T p.A886= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV50159650; called by muse, mutect2, varscan2
- TRPM6 | c.471G>A p.E157= | Silent (SNP) | VAF 50/129 reads (39%) | catalogued as COSV62509043; called by muse, mutect2, varscan2
- TSPYL5 | c.1110C>T p.N370= | Silent (SNP) | VAF 61/294 reads (21%) | catalogued as rs779912049, COSV59071960; called by muse, mutect2, varscan2
- UHRF1BP1L | c.744C>T p.S248= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV54439092; called by muse, mutect2, varscan2
- WDR17 | c.1287G>A p.V429= | Silent (SNP) | VAF 31/137 reads (23%) | catalogued as COSV54576906, COSV54578035; called by muse, mutect2, varscan2
- WDR44 | c.507T>G p.L169= | Silent (SNP) | VAF 30/173 reads (17%) | catalogued as COSV54165135; called by muse, mutect2, varscan2
- WIZ | c.5481C>T p.F1827= (on ENST00000673675 / NM_001371589.1; = p.F732= on NM_021241.3) | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs747864855, COSV54607165; called by muse, mutect2, varscan2
- ZDBF2 | c.1779T>A p.V593= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV65627385; called by muse, mutect2, varscan2
- ZNF140 | c.129C>T p.V43= | Silent (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- ZNF197 | c.1830T>C p.I610= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV60360898; called by muse, mutect2, varscan2
- ZNF229 | c.1377G>A p.K459= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV52159982; called by muse, mutect2, varscan2
- ZNF560 | c.552C>T p.T184= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV56869043; called by muse, mutect2, varscan2
- ZNF711 | c.60C>T p.T20= | Silent (SNP) | VAF 37/254 reads (15%) | catalogued as COSV52151581; called by muse, mutect2, varscan2
- ZNF792 | c.558C>T p.N186= | Silent (SNP) | VAF 130/616 reads (21%) | catalogued as COSV68693693; called by muse, mutect2, varscan2
- BIRC8 | n.1318G>A | RNA (SNP) | VAF 48/146 reads (33%) | catalogued as rs771806712, COSV70346570; called by muse, mutect2, varscan2
- C17orf67 | c.-67T>G | 5'UTR (SNP) | VAF 21/99 reads (21%) | catalogued as COSV67375303; called by muse, mutect2, varscan2
- CARS1 | c.118-22C>T | Intron (SNP) | VAF 31/109 reads (28%) | catalogued as COSV99543430; called by muse, mutect2, varscan2
- CD300LD | chr17:74592539 A>T | 5'Flank (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- DNM1P46 | n.1046C>T | RNA (SNP) | VAF 24/87 reads (28%) | called by muse, mutect2, varscan2
- GABRG2 | c.1249-659G>A | Intron (SNP) | VAF 34/70 reads (49%) | catalogued as rs1216978421; called by muse, mutect2, varscan2
- HERC2P3 | n.829G>A | RNA (SNP) | VAF 54/174 reads (31%) | catalogued as rs1394482372; called by muse, mutect2, varscan2
- KIF16B | c.3498+2915C>T | Intron (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100734843; called by muse, mutect2, varscan2
- MARK2 | c.55-6210C>T | Intron (SNP) | VAF 20/54 reads (37%) | catalogued as COSV100157948; called by muse, mutect2, varscan2
11 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 11 other) are not listed here.
